Somatic mutation profile of tumor specimen TARGET-10-PATRGV-09A (aliquot TARGET-10-PATRGV-09A-01D) from TARGET case TARGET-10-PATRGV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (577 days).
Specimen TARGET-10-PATRGV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8795a133-e954-4c41-933a-69ba31b25569.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATRGV-10A (Blood Derived Normal), aliquot TARGET-10-PATRGV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9acb7c1c-83dc-4521-9b7b-82b650f813df

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Silent 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 100/244 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, varscan2
- CUL3 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.316); catalogued as rs1180155404, COSV52365749; called by muse, mutect2, varscan2
- EFCAB5 | c.1192C>A p.H398N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV57931521; called by muse, mutect2
- EIF2B1 | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs753984869, COSV53016408; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMO1 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs755471523, COSV59957653; called by muse, varscan2
- NFE2 | c.661dup p.E221Gfs*7 | Frame Shift Ins (INS) | VAF 22/62 reads (35%) | catalogued as rs770975576; called by mutect2, varscan2
- NOL6 | c.3253C>A p.L1085I | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53042657; called by muse, mutect2, varscan2
- NOTCH1 | c.4793G>C p.R1598P | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); catalogued as COSV53027279, COSV53097635; called by muse, varscan2
- NOTCH1 | c.4778T>C p.L1593P | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024711; called by muse, varscan2
- NUBP2 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1397797591, COSV51904826; called by muse, mutect2
- PDS5B | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59728725; called by muse, mutect2, varscan2
- ATG4D | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- KLHL20 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRRK1 | c.533C>A p.A178D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRDM10 | c.303G>T p.L101F | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2
- RICTOR | c.3493G>T p.G1165W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); called by muse, mutect2
- C11orf87 | c.330C>A p.R110= | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2
- DENND1C | c.633C>T p.L211= | Silent (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- FZD7 | c.954C>T p.R318= | Silent (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- ULBP3 | c.396C>T p.A132= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as rs753344720; called by muse, mutect2
